Somatic mutation profile of tumor specimen TCGA-DA-A1I5-06A (aliquot TCGA-DA-A1I5-06A-11D-A197-08) from TCGA case TCGA-DA-A1I5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 32.7 years (11,928 days).
Specimen TCGA-DA-A1I5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4e1ab11-e39e-401f-9bb2-db36da4482e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A1I5-10A (Blood Derived Normal), aliquot TCGA-DA-A1I5-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a9f8cc9-6bb5-4d96-8ac2-e575173806e0

The open-access MAF lists 525 somatic variants for this specimen: 355 protein-altering or splice-affecting, 160 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 316, Silent 160, Nonsense Mutation 26, Splice Region 5, Frame Shift Del 3, Intron 3, RNA 2, Splice Site 2, Frame Shift Ins 2, 3'Flank 2, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV60198036; called by muse, mutect2, varscan2
- ABCA13 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.771); catalogued as rs867087150, COSV70025591; called by muse, mutect2, varscan2
- ABCB5 | c.2776C>T p.H926Y (on ENST00000404938 / NM_001163941.2; = p.H481Y on NM_178559.6) | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV51702634; called by muse, mutect2, varscan2
- ABCB9 | c.1631G>A p.G544E (on ENST00000280560 / NM_019625.4; = p.G501E on NM_019624.3) | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99757868, COSV99757932; called by muse, mutect2, varscan2
- ACAD10 | c.2093C>T p.S698F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.368); catalogued as COSV58153637; called by muse, mutect2, varscan2
- ACOT8 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774493885, COSV54168357; called by mutect2, varscan2
- ACTN2 | c.1826C>T p.T609I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100856954; called by muse, mutect2, varscan2
- ACTN2 | c.2304G>A p.R768= | Splice Region (SNP) | VAF 46/107 reads (43%) | catalogued as COSV63971600; called by muse, mutect2, varscan2
- ADAM2 | c.1446G>A p.W482* | Nonsense Mutation (SNP) | VAF 35/65 reads (54%) | catalogued as COSV55858520; called by muse, mutect2, varscan2
- ADAM7 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.802); catalogued as rs905250123, COSV51534663; called by muse, mutect2, varscan2
- ADAM9 | c.178A>T p.R60W | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.866); catalogued as rs1199393727, COSV65958632; called by muse, mutect2, varscan2
- ADAMTS15 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs765641066, COSV54502708; called by muse, mutect2, varscan2
- ADGRG4 | c.2214T>A p.N738K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV54948672; called by muse, mutect2, varscan2
- AGPAT3 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52367458; called by muse, mutect2, varscan2
- AHSG | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV56606944; called by muse, mutect2, varscan2
- AIFM1 | c.1770G>A p.K590= | Splice Region (SNP) | VAF 17/115 reads (15%) | catalogued as COSV54852394; called by muse, mutect2, varscan2
- ALAS2 | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58188145; called by muse, mutect2, varscan2
- ALG10B | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375350214, COSV58142173; called by muse, mutect2, varscan2
- AMPD3 | c.353C>T p.S118F (on ENST00000396553 / NM_001025389.2; = p.S127F on NM_000480.3) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as rs758624728, COSV67329815; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.5636C>T p.S1879L | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV52144327; called by muse, mutect2, varscan2
- ANK3 | c.10187C>A p.S3396Y | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55042938; called by muse, mutect2, varscan2
- ANK3 | c.3103C>T p.P1035S (on ENST00000280772 / NM_001320874.2; = p.P169S on NM_001149.3) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55042947; called by muse, mutect2, varscan2
- ANKEF1 | c.1279G>T p.G427W | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65691917; called by mutect2, varscan2
- ANKRD28 | c.2482C>T p.H828Y | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769141016, COSV67516786; called by muse, mutect2, varscan2
- AOAH | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777229386, COSV51735087; called by muse, mutect2, varscan2
- APOB | c.13159G>A p.E4387K | Missense Mutation (SNP) | VAF 227/761 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV51922117; called by muse, mutect2, varscan2
- ARAP2 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 53/198 reads (27%) | catalogued as COSV58282085; called by muse, mutect2, varscan2
- ARHGEF2 | c.1330G>A p.E444K (on ENST00000361247 / NM_001162383.2; = p.E416K on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58106064; called by muse, mutect2, varscan2
- ARL5A | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV54469175; called by muse, mutect2
- ARNT | c.854T>G p.V285G | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV62229566; called by muse, varscan2
- ASPHD1 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV100435766; called by muse, mutect2, varscan2
- ASTN1 | c.3274C>T p.P1092S | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.991); catalogued as COSV62490321; called by muse, mutect2, varscan2
- ATF7 | c.440T>C p.V147A (on ENST00000548446 / NM_001366555.2; = p.V136A on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as COSV60642046; called by muse, mutect2, varscan2
- ATM | c.8275C>T p.P2759S | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764906663, COSV53724261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10D | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as COSV56703429; called by muse, mutect2, varscan2
- ATP1A3 | c.2155G>C p.G719R (on ENST00000545399 / NM_001256214.2; = p.G706R on NM_152296.5) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM145541, COSV100132380, COSV57484860; called by muse, mutect2
- ATP4A | c.2119C>T p.Q707* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV52865317; called by muse, mutect2, varscan2
- ATP7A | c.1252A>C p.T418P | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV58441977; called by muse, mutect2, varscan2
- ATP8B4 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV52708558; called by muse, mutect2, varscan2
- BAG6 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 176/585 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs1432851591, COSV52987700; called by muse, mutect2, varscan2
- BAIAP3 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.24); catalogued as rs1271529246, COSV50103501, COSV50105838; called by muse, mutect2, varscan2
- BAZ2B | c.4684C>T p.L1562F | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs758666979, COSV58595224, COSV58600037; called by muse, varscan2
- BLK | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775313404, COSV52049165; called by muse, mutect2, varscan2
- BMP3 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV51081577; called by muse, mutect2, varscan2
- BMPER | c.906A>C p.K302N | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as COSV51810987; called by muse, mutect2, varscan2
- BMT2 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769995782, COSV51774470; called by muse, mutect2, varscan2
- C1orf112 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53676456; called by muse, mutect2, varscan2
- C9orf131 | c.3040G>A p.G1014S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.083); catalogued as COSV56609502; called by muse, mutect2, varscan2
- CALD1 | c.1450C>T p.R484* (on ENST00000361675 / NM_033138.4; = p.R229* on NM_004342.7) | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV62644966, COSV62653646; called by muse, mutect2, varscan2
- CAPZA3 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 24/73 reads (33%) | catalogued as rs1189957548, COSV56848485; called by muse, mutect2, varscan2
- CARD11 | c.2996T>C p.M999T | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV67796663; called by muse, mutect2, varscan2
- CARD19 | c.248C>G p.A83G | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV100968686; called by muse, mutect2, varscan2
- CBFA2T3 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.299); catalogued as COSV51922769; called by muse, mutect2, varscan2
- CCDC148 | c.1339A>T p.I447F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV51753655; called by muse, mutect2, varscan2
- CCDC172 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV60936518; called by muse, mutect2, varscan2
- CD163L1 | c.2135G>A p.G712E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867073039, COSV58010539; called by muse, mutect2, varscan2
- CD180 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs751266743, COSV56516687; called by muse, mutect2, varscan2
- CD19 | c.1512G>A p.M504I (on ENST00000324662 / NM_001178098.2; = p.M503I on NM_001770.6) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61187678; called by mutect2, varscan2
- CDH16 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs765276757, COSV55334620; called by muse, mutect2, varscan2
- CDH18 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56899158, COSV56955197; called by muse, mutect2, varscan2
- CENPI | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1247919508, COSV54500442; called by muse, mutect2, varscan2
- CER1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1375696718, COSV66602861; called by muse, mutect2, varscan2
- CFAP206 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV51532449; called by muse, mutect2, varscan2
- CFAP45 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV63647887; called by muse, mutect2, varscan2
- CFTR | c.3380G>A p.G1127E | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs1434504483, CD141630, CM941982, COSV50040585, COSV50057922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHTF8 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776752545, COSV99544660; called by muse, mutect2, varscan2
- CLEC5A | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69396684; called by muse, mutect2, varscan2
- CLSPN | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.146); catalogued as COSV52046237; called by muse, mutect2, varscan2
- COL11A1 | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100617865, COSV62171984; called by muse, mutect2, varscan2
- COL25A1 | c.492G>A p.R164= | Splice Region (SNP) | VAF 25/75 reads (33%) | catalogued as COSV67645938; called by muse, mutect2, varscan2
- COL5A2 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV66406798; called by muse, mutect2, varscan2
- CPB1 | c.1095G>A p.W365* | Nonsense Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as COSV51571103; called by muse, mutect2, varscan2
- CR2 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.859); catalogued as COSV65505925; called by muse, mutect2, varscan2
- CSN2 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.609); catalogued as rs764809165, COSV61991721; called by muse, mutect2, varscan2
- CTSL | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as rs1040871888, COSV58245611; called by muse, mutect2, varscan2
- CYLC1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV100254829, COSV61409685; called by muse, mutect2, varscan2
- CYP2C9 | c.1147A>T p.K383* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV53246243; called by muse, varscan2
- DCC | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100503138, COSV59082291; called by muse, mutect2, varscan2
- DCLRE1B | c.1537C>T p.Q513* | Nonsense Mutation (SNP) | VAF 46/185 reads (25%) | catalogued as COSV65812036; called by muse, mutect2, varscan2
- DDX10 | c.1829C>T p.T610I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59431239; called by muse, mutect2, varscan2
- DDX53 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.4); catalogued as COSV60068454; called by muse, mutect2, varscan2
- DEFB114 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs752246175, COSV59037087; called by muse, mutect2, varscan2
- DENND3 | c.3439G>A p.G1147R | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776557233, COSV52800609; called by muse, mutect2, varscan2
- DGKK | c.3208C>T p.L1070F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV65706201, COSV65709246; called by muse, mutect2, varscan2
- DLG1 | c.2233C>T p.H745Y (on ENST00000419354 / NM_001290983.1; = p.H767Y on NM_004087.2) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs746862777, COSV58377373; called by mutect2, varscan2
- DNAH10 | c.11107G>A p.D3703N (on ENST00000409039; = p.D3642N on NM_207437.3) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as rs1412769384, COSV68987463; called by muse, mutect2, varscan2
- DNAH3 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1344227177, COSV99770086; called by mutect2, varscan2
- DNAH7 | c.6038C>T p.A2013V | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV56750743; called by muse, mutect2, varscan2
- DNAH8 | c.5119G>A p.D1707N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs267601015, COSV100543697, COSV59422745; called by muse, mutect2, varscan2
- DNAH8 | c.5560G>A p.E1854K | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59422778; called by muse, mutect2, varscan2
- DNAH8 | c.7649G>A p.G2550E | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59422807; called by muse, mutect2, varscan2
- DNAH8 | c.8760G>A p.M2920I | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV59422840; called by muse, mutect2, varscan2
- DOCK11 | c.2577G>A p.M859I | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.041); catalogued as COSV52233131; called by muse, mutect2, varscan2
- DOCK3 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.579); catalogued as COSV56501219; called by muse, mutect2, varscan2
- DPP6 | c.1148T>C p.I383T (on ENST00000377770 / NM_001364500.2; = p.I321T on NM_001936.5) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59596196; called by muse, mutect2, varscan2
- DSC1 | c.2566G>A p.G856S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57141412; called by muse, mutect2, varscan2
- DSG3 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV57123975; called by muse, mutect2, varscan2
- DSP | c.6047G>A p.G2016E | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs771165835, COSV65790899; called by muse, mutect2, varscan2
- DSP | c.7438C>A p.Q2480K | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.437); catalogued as COSV65790903; called by muse, varscan2
- DYNLT3 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV101059469; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1547C>T p.P516L (on ENST00000361735 / NM_015935.5; = p.P430L on NM_014955.3) | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV62282435; called by muse, mutect2, varscan2
- EFCAB3 | c.266A>C p.Y89S | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.425); catalogued as COSV59499764; called by muse, mutect2, varscan2
- ELL2 | c.1739C>T p.S580F | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52980908, COSV52982342; called by muse, mutect2, varscan2
- ELOVL1 | c.240C>T p.F80= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as COSV60521563; called by muse, mutect2, varscan2
- ELP3 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV56457394; called by muse, mutect2, varscan2
- EPB41L2 | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs990389981, COSV61352863; called by muse, mutect2, varscan2
- EPHB6 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as COSV63890290; called by muse, mutect2, varscan2
- EPS15L1 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV50167136; called by muse, mutect2, varscan2
- ERBB3 | c.2413dup p.A805Gfs*22 | Frame Shift Ins (INS) | VAF 18/82 reads (22%) | catalogued as rs1565860436; called by mutect2, pindel, varscan2
- ERCC6L | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1268887460, COSV57819277; called by muse, mutect2, varscan2
- EVX1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56084723; called by muse, mutect2, varscan2
- EXD1 | c.708G>A p.W236* | Nonsense Mutation (SNP) | VAF 61/161 reads (38%) | catalogued as COSV59252609; called by muse, mutect2, varscan2
- F2 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377462682, COSV61314662; called by muse, mutect2, varscan2
- F8 | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV64269431; called by muse, mutect2, varscan2
- FAAH2 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs1410129459, COSV100887373, COSV66504753; called by muse, mutect2, varscan2
- FAM227B | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.187); catalogued as rs1481954359, COSV54804771; called by muse, mutect2, varscan2
- FAT1 | c.6607C>T p.H2203Y | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs377148743; called by muse, mutect2, varscan2
- FGA | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57392547; called by muse, mutect2, varscan2
- FGR | c.1357A>C p.T453P | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV64969172; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV100437675, COSV58544843; called by muse, mutect2, varscan2
- FREM1 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66517197; called by muse, mutect2, varscan2
- FRMPD2 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.425); catalogued as COSV59714818; called by mutect2, varscan2
- FSCN3 | c.239G>C p.G80A | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50000128; called by muse, mutect2, varscan2
- GANC | c.1486T>A p.F496I | Missense Mutation (SNP) | VAF 50/188 reads (27%) | PolyPhen benign (0.221); catalogued as COSV58807052; called by mutect2, varscan2
- GOLGA6A | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1482970527, COSV51803891; called by muse, mutect2, varscan2
- GPRC5A | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs746863431, COSV50007264; called by muse, mutect2, varscan2
- HECW1 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as COSV101224195; called by muse, varscan2
- HECW1 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV67821016; called by muse, varscan2
- HEMK1 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1366051283, COSV51749832; called by muse, mutect2, varscan2
- HEPH | c.1188G>A p.M396I (on ENST00000343002; = p.M129I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100295201, COSV57958565; called by muse, mutect2, varscan2
- HERC4 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV53268184; called by muse, mutect2, varscan2
- HGF | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.98); catalogued as rs1221162897, COSV55945014; called by muse, mutect2, varscan2
- HIP1R | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53438895; called by mutect2, varscan2
- HMBOX1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as COSV55065683; called by muse, mutect2, varscan2
- HTR4 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV58789149; called by muse, mutect2, varscan2
- IGF1R | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51269524; called by muse, mutect2, varscan2
- INIP | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV65295068, COSV65295394; called by muse, mutect2, varscan2
- INPP5J | c.1290G>A p.W430* (on ENST00000331075 / NM_001284285.2; = p.W62* on NM_001002837.2) | Nonsense Mutation (SNP) | VAF 50/154 reads (32%) | catalogued as COSV58511347; called by muse, mutect2, varscan2
- INSL6 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 93/129 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV67562463; called by muse, mutect2, varscan2
- INTS9 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV68433106; called by muse, mutect2, varscan2
- IP6K2 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60792638; called by muse, mutect2, varscan2
- ITGA5 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53215201; called by muse, mutect2
- ITGA8 | c.2119G>A p.G707R | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.588); catalogued as COSV65224115; called by muse, varscan2
- ITPR1 | c.7214G>A p.G2405E (on ENST00000354582; = p.G2350E on NM_002222.7) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100232863, COSV56999571; called by muse, mutect2, varscan2
- JAML | c.493G>A p.V165M (on ENST00000356289 / NM_001098526.2; = p.V155M on NM_153206.3) | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.075); catalogued as rs753671009, COSV52626313; called by mutect2, varscan2
- KANSL3 | c.2137C>T p.P713S (on ENST00000666923 / NM_001349262.2; = p.P687S on NM_001115016.3) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs1056525633, COSV62615610; called by muse, mutect2
- KAT6A | c.1101A>T p.K367N | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV55902273; called by mutect2, varscan2
- KCNA6 | c.1258A>T p.M420L | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV99768908; called by mutect2, varscan2
- KCNA6 | c.1259T>G p.M420R | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99768913; called by muse, mutect2, varscan2
- KCNAB1 | c.281T>C p.L94P (on ENST00000490337 / NM_172160.3; = p.L83P on NM_003471.3) | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56740613; called by muse, mutect2, varscan2
- KCND3 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56174441; called by muse, mutect2, varscan2
- KCNK17 | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771075879, COSV64684728; called by muse, mutect2, varscan2
- KCNT2 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as COSV54062653; called by muse, mutect2, varscan2
- KCTD19 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs769658974, COSV58570966; called by muse, mutect2, varscan2
- KDR | c.162G>A p.R54= | Splice Region (SNP) | VAF 25/80 reads (31%) | catalogued as COSV55757457; called by muse, mutect2, varscan2
- KIR3DL3 | c.356-1G>A p.X119_splice | Splice Site (SNP) | VAF 32/155 reads (21%) | catalogued as rs948768549; called by muse, mutect2, varscan2
- KLHL32 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1002538688, COSV65110305; called by muse, mutect2, varscan2
- KMT2A | c.11258C>T p.A3753V | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV63281515; called by muse, mutect2, varscan2
- KMT2C | c.1294T>C p.C432R | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV51278201; called by muse, mutect2, varscan2
- KNTC1 | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV61078710; called by muse, mutect2
- KRT10 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.425); catalogued as rs1211426625, COSV54088219; called by muse, mutect2, varscan2
- KRT6A | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.332); catalogued as COSV58103484; called by muse, mutect2, varscan2
- KRT9 | c.1226T>G p.L409R | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55851400; called by muse, mutect2, varscan2
- L1TD1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100776638, COSV63133048; called by muse, mutect2, varscan2
- LAMC1 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 43/370 reads (12%) | catalogued as COSV51132157, COSV51189587; called by muse, mutect2, varscan2
- LINS1 | c.2191C>T p.L731F | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59077806, COSV59078446; called by muse, mutect2, varscan2
- LRBA | c.6730C>T p.P2244S | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63949416; called by muse, mutect2, varscan2
- LRBA | c.6593C>T p.S2198L | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63949422; called by muse, mutect2, varscan2
- LRRC17 | c.876T>G p.H292Q | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.158); catalogued as COSV50863961; called by muse, mutect2, varscan2
- LRRC6 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs868505984, COSV51537459; called by muse, mutect2, varscan2
- LTBP1 | c.2841G>A p.M947I (on ENST00000404816 / NM_206943.4; = p.M621I on NM_000627.4) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV63179097; called by muse, mutect2, varscan2
- LTBP1 | c.3257G>A p.G1086E (on ENST00000404816 / NM_206943.4; = p.G760E on NM_000627.4) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.99); catalogued as COSV55375108; called by muse, mutect2, varscan2
- LTBP2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV56204440, COSV99999784; called by muse, mutect2, varscan2
- LTBP4 | c.4288C>T p.P1430S (on ENST00000308370 / NM_001042544.1; = p.P1393S on NM_003573.2) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV52575530; called by muse, mutect2, varscan2
- MAGEA10 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as rs1240123036, COSV54882680; called by muse, mutect2, varscan2
- MAGEA4 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as rs757230613, COSV52340094; called by muse, mutect2, varscan2
- MAP3K10 | c.1763C>T p.S588L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV53420233; called by mutect2, varscan2
- MARCHF11 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 81/181 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs781465967, COSV100198122, COSV60125763; called by muse, mutect2, varscan2
- MB21D2 | c.280C>G p.R94G | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV66661371; called by muse, mutect2, varscan2
- MED13L | c.2798C>A p.S933* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV56115334; called by muse, mutect2, varscan2
- MGAM | c.4411C>T p.P1471S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as rs766765023, COSV72073532; called by muse, mutect2, varscan2
- MISP | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs368652913; called by muse, mutect2, varscan2
- MISP | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs1366745231, COSV53118646; called by muse, mutect2, varscan2
- MMP3 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55404953; called by muse, mutect2, varscan2
- MRAP2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57631363, COSV57632070; called by muse, mutect2, varscan2
- MRGPRX1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs867594179, COSV57105773; called by muse, mutect2, varscan2
- MROH7 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.143); catalogued as rs368337420; called by muse, mutect2, varscan2
- MSH3 | c.1853T>G p.L618W | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54144006; called by muse, mutect2, varscan2
- MVP | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as COSV62421295; called by muse, mutect2, varscan2
- MX2 | c.1865C>T p.S622F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV58094870; called by muse, mutect2, varscan2
- MYO5A | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV62556339; called by muse, mutect2, varscan2
- MYO5B | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV53210513; called by muse, mutect2, varscan2
- NAALAD2 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.984); catalogued as rs150474449; called by muse, mutect2, varscan2
- NAB1 | c.647A>G p.N216S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV61608102; called by muse, mutect2, varscan2
- NAF1 | c.717+2T>C p.X239_splice | Splice Site (SNP) | VAF 3/12 reads (25%) | catalogued as COSV56803146; called by muse, mutect2
- NBEA | c.8740C>T p.H2914Y | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.181); catalogued as rs984437195, COSV59757994; called by muse, mutect2, varscan2
- NEK4 | c.1637A>G p.H546R | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs1485180318, COSV51778534; called by muse, mutect2, varscan2
- NID1 | c.2462C>T p.P821L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as COSV51614538; called by muse, varscan2
- NIPBL | c.7133C>T p.P2378L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs1355833943, COSV56941450; called by muse, mutect2, varscan2
- NLGN4X | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52003299; called by muse, mutect2, varscan2
- NLRP3 | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV100276261, COSV60219343; called by muse, varscan2
- NLRP4 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV56707269, COSV56710768; called by muse, mutect2, varscan2
- NLRP8 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); catalogued as COSV52582949; called by muse, mutect2, varscan2
- NPAP1 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.801); catalogued as rs868115699, COSV61504054; called by muse, mutect2, varscan2
- NPHS1 | c.3514C>T p.P1172S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.234); catalogued as rs777436326, COSV62286211; called by muse, mutect2, varscan2
- NPSR1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV62198592; called by muse, mutect2
- NRROS | c.62A>G p.N21S | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60744541; called by muse, mutect2, varscan2
- NRXN3 | c.2776G>A p.G926R (on ENST00000335750 / NM_001330195.2; = p.G553R on NM_004796.6) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59711888; called by muse, mutect2, varscan2
- NTF3 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.17); catalogued as COSV58417098; called by muse, mutect2, varscan2
- NTNG1 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV53961773; called by muse, mutect2, varscan2
- NTNG1 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.266); catalogued as COSV53961793, COSV53989916; called by muse, mutect2, varscan2
- NWD1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60337179; called by muse, mutect2, varscan2
- OR10A7 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 68/230 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); catalogued as COSV58277638; called by muse, mutect2, varscan2
- OR10J1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373330432, COSV101419901, COSV71128120; called by muse, mutect2, varscan2
- OR13H1 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58547015, COSV58547486; called by muse, mutect2, varscan2
- OR1C1 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.61); catalogued as COSV68715336, COSV68716066; called by muse, mutect2, varscan2
- OR2J2 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs748554260, COSV65847681; called by muse, varscan2
- OR2M3 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 142/274 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV71758836; called by muse, mutect2, varscan2
- OR2T33 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1298197518, COSV58813710; called by muse, varscan2
- OR4A16 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); catalogued as rs1389734335, COSV59041785; called by muse, mutect2, varscan2
- OR4E2 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1454178293, COSV100330061, COSV57731327; called by mutect2, varscan2
- OR4N5 | c.881T>G p.V294G | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV61319989; called by muse, mutect2, varscan2
- OR5D18 | c.214T>A p.F72I | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV61736060; called by muse, mutect2, varscan2
- OR5M8 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.617); catalogued as COSV59115639; called by mutect2, varscan2
- OR6A2 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV60264395; called by muse, mutect2, varscan2
- OSBPL7 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1277565837, COSV50106488; called by mutect2, varscan2
- PAK6 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146905959, COSV53044260; called by muse, varscan2
- PCDHB14 | c.2323C>T p.Q775* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV53386310, COSV53389919; called by muse, mutect2, varscan2
- PCDHB8 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs782235899, COSV50769178; called by muse, mutect2, varscan2
- PCDHB9 | c.149A>T p.K50M | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV53374957; called by mutect2, varscan2
- PEG3 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV55623836; called by muse, mutect2, varscan2
- PIK3C2B | c.4046G>A p.R1349Q | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs560059936, COSV65808873; called by muse, mutect2, varscan2
- PJA1 | c.1333C>T p.R445* (on ENST00000361478 / NM_145119.4; = p.R257* on NM_022368.5) | Nonsense Mutation (SNP) | VAF 58/157 reads (37%) | catalogued as COSV64052550; called by muse, mutect2, varscan2
- PKHD1 | c.10691C>T p.A3564V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV100943469, COSV64380827; called by muse, mutect2, varscan2
- PLCB1 | c.2158G>A p.G720R | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV62044282; called by muse, varscan2
- PLCB1 | c.2159G>A p.G720E | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV62039711; called by muse, varscan2
- PLCB1 | c.2183A>G p.E728G | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV62036791, COSV62052506; called by muse, varscan2
- PLCB4 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV53791968; called by muse, mutect2, varscan2
- PLCB4 | c.2198C>T p.T733I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370308281; called by muse, mutect2, varscan2
- PLCZ1 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760730677, COSV56848471; called by muse, mutect2, varscan2
- PLXNB2 | c.2903C>T p.S968F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs745397200, COSV63779968, COSV63784167; called by muse, mutect2, varscan2
- PLXNB3 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62795320; called by muse, mutect2
- PML | c.2533G>A p.A845T | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs1223190247, COSV51441707; called by muse, mutect2, varscan2
- PNMA8A | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs763299484, COSV58135574; called by muse, mutect2, varscan2
- POTEF | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV62539422; called by muse, mutect2, varscan2
- PREX2 | c.2722C>T p.R908C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as rs367863793, COSV99908118; called by mutect2, varscan2
- PREX2 | c.4669C>T p.R1557C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs752310428, COSV55749284; called by mutect2, varscan2
- PRICKLE3 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV66234017; called by muse, mutect2, varscan2
- PRUNE2 | c.1357G>C p.G453R | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100945243, COSV65037676, COSV65040370; called by muse, mutect2, varscan2
- PSG8 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60609273; called by muse, mutect2, varscan2
- PTGER3 | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV100657329; called by muse, mutect2, varscan2
- PTPRK | c.4025G>A p.R1342Q (on ENST00000368215 / NM_001291984.2; = p.R1343Q on NM_002844.4) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as rs754669062, COSV63890691; called by muse, mutect2, varscan2
- PTPRO | c.1313A>C p.H438P | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV55502774; called by muse, mutect2, varscan2
- PTPRT | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV61958362; called by muse, mutect2, varscan2
- RBM11 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs763112579, COSV68747915; called by muse, mutect2, varscan2
- RECK | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65034515; called by muse, mutect2, varscan2
- RGS21 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101314018, COSV69881457; called by muse, mutect2, varscan2
- RNF133 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs113296018; called by muse, mutect2, varscan2
- RNF17 | c.3686G>A p.W1229* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV55033406; called by muse, mutect2, varscan2
- ROS1 | c.5575G>A p.E1859K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.468); catalogued as COSV100877631, COSV63858030; called by muse, mutect2, varscan2
- RP1L1 | c.3835G>A p.D1279N | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66751433; called by muse, mutect2, varscan2
- RPS6KA2 | c.1840G>A p.G614R | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55815288; called by muse, mutect2, varscan2
- RPS6KA6 | c.1301T>C p.V434A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV53115756; called by muse, mutect2
- RTL3 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV58182989; called by muse, mutect2, varscan2
- RUVBL2 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as COSV55484121; called by muse, mutect2, varscan2
- SALL1 | c.3262G>A p.E1088K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV51752818; called by muse, mutect2, varscan2
- SALL1 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 38/120 reads (32%) | catalogued as COSV51752826; called by muse, mutect2, varscan2
- SAMD7 | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59416808; called by muse, mutect2, varscan2
- SETDB1 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV54976711; called by muse, mutect2, varscan2
- SH3KBP1 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as COSV65646006; called by muse, mutect2, varscan2
- SIGLECL1 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as rs948535377, COSV57063316, COSV57064615; called by mutect2, varscan2
- SIKE1 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV50258492; called by muse, mutect2, varscan2
- SLC16A9 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.134); catalogued as COSV68098162; called by muse, mutect2, varscan2
- SLC19A3 | c.875T>C p.F292S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV51451138, COSV51451306; called by muse, mutect2, varscan2
- SLC30A10 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV63070343, COSV63076143; called by muse, mutect2, varscan2
- SLC4A1 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.045); catalogued as COSV52258124; called by muse, mutect2
- SLC4A10 | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV55763415; called by mutect2, varscan2
- SLC6A13 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as rs781142259, COSV58255103; called by muse, mutect2, varscan2
- SMAD3 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59280191; called by muse, mutect2, varscan2
- SNAPC1 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV53519058; called by muse, mutect2, varscan2
- SNCAIP | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV54401525; called by muse, mutect2, varscan2
- SPAG17 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60452821; called by mutect2, varscan2
- SPEF2 | c.2942G>A p.G981E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.121); catalogued as rs866774074, COSV61543955; called by muse, mutect2, varscan2
- SPRED1 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 39/130 reads (30%) | catalogued as COSV54433863; called by muse, mutect2, varscan2
- SRGAP3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as COSV64530103; called by muse, varscan2
- SSH1 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100425803; called by muse, mutect2, varscan2
- STBD1 | c.948T>G p.D316E | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV52953312; called by muse, mutect2, varscan2
- STON1 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59125692; called by muse, mutect2, varscan2
- SYNJ1 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs146507597; called by muse, mutect2, varscan2
- TADA3 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.745); catalogued as COSV57332405, COSV57333213; called by muse, mutect2, varscan2
- TAF7L | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV61256201; called by muse, mutect2, varscan2
- TAT | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761596094, COSV63532238; called by muse, mutect2
- TBX15 | c.815T>A p.F272Y (on ENST00000369429 / NM_001330677.2; = p.F166Y on NM_152380.3) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52867027; called by mutect2, varscan2
- TBX19 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV63196614; called by muse, mutect2, varscan2
- TEX55 | c.1016A>C p.H339P | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55210135, COSV55210325; called by muse, mutect2, varscan2
- THRB | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs776036533, COSV62833903; called by muse, mutect2, varscan2
- TJP2 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs539919973, COSV55262414; called by muse, mutect2, varscan2
- TLE6 | c.458G>A p.W153* (on ENST00000246112 / NM_001143986.2; = p.W30* on NM_024760.3) | Nonsense Mutation (SNP) | VAF 42/98 reads (43%) | catalogued as rs760419747, COSV55734261; called by muse, mutect2, varscan2
- TLL1 | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as rs1165249462, COSV50261280; called by muse, mutect2, varscan2
- TMEM179B | c.388A>T p.N130Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV99585415; called by muse, varscan2
- TMEM201 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61050691; called by muse, mutect2, varscan2
- TMEM37 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.246); catalogued as COSV50026740; called by muse, mutect2, varscan2
- TMEM61 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV64873314; called by muse, mutect2, varscan2
- TMPRSS11A | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58356771; called by muse, mutect2, varscan2
- TMPRSS13 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs1401058713, COSV70625597; called by mutect2, varscan2
- TNFAIP1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50228132; called by muse, mutect2, varscan2
- TNMD | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs761145360, COSV65976754; called by muse, varscan2
- TNN | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as COSV53421082; called by muse, mutect2, varscan2
- TNS1 | c.5174C>T p.S1725F | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99411691; called by muse, mutect2, varscan2
- TONSL | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV101340300; called by muse, mutect2, varscan2
- TONSL | c.1980G>A p.M660I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as COSV101340301; called by mutect2, varscan2
- TRAK2 | c.1745G>T p.G582V | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV60270017; called by muse, mutect2, varscan2
- TRAPPC11 | c.508A>G p.K170E | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58214409; called by muse, mutect2, varscan2
- TREML2 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.125); catalogued as COSV72439005; called by muse, mutect2, varscan2
- TRHDE | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53831264; called by muse, mutect2, varscan2
- TRHR | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 85/285 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs762653084, COSV61232685; called by muse, mutect2, varscan2
- TRIM37 | c.1588C>T p.Q530* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV51881136; called by mutect2, varscan2
- TRPC4 | c.1905G>A p.W635* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV58989505; called by muse, mutect2, varscan2
- TTN | c.39694G>A p.E13232K (on ENST00000591111; = p.E5808K on NM_003319.4) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | PolyPhen benign (0.443); catalogued as COSV59870776, COSV60365650; called by muse, mutect2, varscan2
- TTN | c.33685G>A p.E11229K (on ENST00000591111; = p.E10302K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | PolyPhen benign (0.009); catalogued as COSV59986216; called by muse, mutect2, varscan2
- UBR1 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.694); catalogued as COSV51925690; called by muse, mutect2, varscan2
- UGT2B15 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 105/385 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.33); catalogued as rs774007183, COSV57732792; called by muse, mutect2, varscan2
- UGT2B4 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV59315085; called by muse, mutect2, varscan2
- UGT2B7 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV59441838, COSV59445585; called by muse, mutect2, varscan2
- UNC13C | c.5101G>A p.E1701K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs768039530, COSV52841291, COSV52849785; called by muse, mutect2, varscan2
- USH1C | c.1064G>A p.R355K | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as COSV50013920; called by muse, mutect2, varscan2
- USP6 | c.1984G>A p.A662T | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51473104; called by muse, mutect2, varscan2
- VAMP7 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV52901164; called by muse, mutect2, varscan2
- VIL1 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV50285336; called by muse, mutect2, varscan2
- VSTM1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as COSV58073752; called by muse, mutect2, varscan2
- VWF | c.6220C>T p.P2074S | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.416); catalogued as COSV54610762; called by muse, mutect2, varscan2
- WFDC8 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51488432; called by muse, mutect2, varscan2
- XIRP2 | c.479A>G p.N160S (on ENST00000628543; = p.N335S on NM_152381.6) | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV54680822; called by muse, mutect2, varscan2
- ZAN | c.5354C>T p.S1785F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61804555; called by muse, mutect2
- ZC3H18 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.736); catalogued as COSV99964389; called by muse, mutect2, varscan2
- ZFHX3 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51707035; called by muse, mutect2, varscan2
- ZFP64 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53796133; called by muse, mutect2, varscan2
- ZKSCAN8 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 29/76 reads (38%) | catalogued as COSV57636795; called by muse, mutect2, varscan2
- ZNF185 | c.1496G>A p.G499E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV59273966; called by muse, mutect2
- ZNF215 | c.839G>A p.W280* | Nonsense Mutation (SNP) | VAF 40/106 reads (38%) | catalogued as COSV53491496; called by muse, mutect2, varscan2
- ZNF223 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV71571828; called by muse, mutect2, varscan2
- ZNF536 | c.1878G>A p.M626I | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV62817745; called by muse, mutect2, varscan2
- ZNF711 | c.1076G>A p.R359K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV52151132; called by muse, mutect2
- ZNF75D | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV66132340; called by muse, mutect2, varscan2
- ZZEF1 | c.8042T>G p.L2681R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755055310, COSV67555823; called by muse, mutect2, varscan2
- ERICH3 | c.3610del p.L1204* | Frame Shift Del (DEL) | VAF 42/192 reads (22%) | called by mutect2, pindel, varscan2
- FCGBP | c.7738C>T p.P2580S | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- IGHV1OR21-1 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 54/429 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- LNPK | c.153_155delinsTG p.L53Sfs*7 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | called by pindel, varscan2*
- PRAMEF14 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- SLCO1C1 | c.922_923delinsA p.S308Ifs*12 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by pindel, varscan2*
- TPRN | c.942_943dup p.L315Pfs*136 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | called by mutect2, varscan2
- ABCA13 | c.12078G>A p.T4026= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as rs749688838, COSV71282976; called by muse, mutect2, varscan2
- ABCC1 | c.3453C>T p.V1151= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV60679490; called by muse, mutect2, varscan2
- ACTN2 | c.1827C>T p.T609= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs778030507, COSV100856955; called by mutect2, varscan2
- ADAM32 | c.2151C>T p.F717= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as rs752179563, COSV65946943; called by muse, mutect2, varscan2
- ADAP2 | c.909T>C p.F303= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV58294842; called by muse, mutect2, varscan2
- ADGRV1 | c.5985G>A p.Q1995= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV67977864; called by muse, mutect2, varscan2
- AKR1D1 | c.786C>T p.F262= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as COSV54335988; called by muse, mutect2, varscan2
- AMER3 | c.876G>A p.V292= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV58465020; called by muse, mutect2, varscan2
- AOAH | c.1488C>T p.F496= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV51735076; called by muse, mutect2, varscan2
- ASPHD1 | c.303A>G p.Q101= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV100435765; called by muse, mutect2, varscan2
- ASRGL1 | c.349C>T p.L117= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV57123335; called by muse, mutect2, varscan2
- ASTN2 | c.3939C>T p.I1313= (on ENST00000313400 / NM_001365069.1; = p.I1262= on NM_014010.5) | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV55998020; called by muse, mutect2, varscan2
- ATP2A3 | c.420C>T p.I140= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV59225822; called by muse, mutect2, varscan2
- BCL11A | c.1917C>T p.F639= (on ENST00000335712 / NM_001365609.1; = p.F673= on NM_018014.4) | Silent (SNP) | VAF 151/520 reads (29%) | catalogued as COSV59623681; called by muse, mutect2, varscan2
- C6orf118 | c.438C>T p.F146= | Silent (SNP) | VAF 48/134 reads (36%) | catalogued as rs572724396, COSV57812256; called by muse, mutect2, varscan2
- CAMK1G | c.981G>A p.P327= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as rs147599953; called by muse, mutect2, varscan2
- CARD19 | c.249C>T p.A83= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV100968687; called by muse, mutect2, varscan2
- CCDC178 | c.24C>T p.S8= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV55757765; called by muse, mutect2, varscan2
- CCDC71 | c.1341C>T p.I447= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV58909701; called by muse, mutect2, varscan2
- CDH17 | c.1269G>A p.E423= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs758545974, COSV99217918; called by muse, mutect2, varscan2
- CDHR2 | c.609G>A p.E203= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as COSV56134311; called by muse, mutect2, varscan2
- CENPT | c.411C>T p.L137= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs760752826, COSV54648038; called by muse, mutect2, varscan2
- CERS5 | c.1137G>A p.R379= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as COSV58188203, COSV58188337; called by muse, mutect2, varscan2
- CFAP100 | c.906G>A p.G302= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs958027704, COSV61502307; called by muse, mutect2
- CFAP206 | c.1728G>A p.K576= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV65806326; called by muse, mutect2, varscan2
- CHRNA9 | c.1026G>A p.L342= | Silent (SNP) | VAF 95/290 reads (33%) | catalogued as COSV59573406; called by muse, mutect2, varscan2
- CHTF8 | c.147C>T p.I49= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs776820006, COSV99544663; called by muse, mutect2, varscan2
- CLEC4M | c.165C>A p.L55= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV50216697; called by mutect2, varscan2
- CLEC5A | c.156G>A p.G52= | Silent (SNP) | VAF 78/182 reads (43%) | catalogued as COSV69396690; called by muse, mutect2, varscan2
- COL11A2 | c.4977C>T p.A1659= (on ENST00000341947 / NM_080680.3; = p.A1552= on NM_080679.2) | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV59493344; called by muse, mutect2
- CPAMD8 | c.2166C>T p.F722= (on ENST00000651564; = p.F675= on NM_015692.5) | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs1211972154, COSV52230746; called by muse, mutect2, varscan2
- CR1 | c.3303G>A p.G1101= | Silent (SNP) | VAF 108/239 reads (45%) | catalogued as COSV65455594; called by muse, mutect2, varscan2
- CRP | c.372C>T p.I124= | Silent (SNP) | VAF 125/245 reads (51%) | catalogued as rs753294711, COSV54812508; called by muse, mutect2, varscan2
- CSMD3 | c.4728C>T p.F1576= (on ENST00000297405 / NM_001363185.1; = p.F1472= on NM_052900.3) | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV52094619; called by muse, mutect2, varscan2
- CUL5 | c.1644T>A p.P548= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV67607969; called by mutect2, varscan2
- CYLC1 | c.651G>A p.K217= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV61409700; called by muse, mutect2
- CYP4F8 | c.276G>A p.L92= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV100358200, COSV57852982; called by muse, varscan2
- CYP4Z1 | c.978C>T p.I326= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV61963651; called by muse, mutect2, varscan2
- DAB2 | c.1443C>G p.P481= | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as COSV57912141; called by muse, mutect2, varscan2
- DDOST | c.903G>A p.K301= (on ENST00000415136; = p.K284= on NM_005216.5) | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs762664774, COSV58630312; called by muse, mutect2, varscan2
- DENND2A | c.660G>A p.S220= | Silent (SNP) | VAF 82/172 reads (48%) | catalogued as rs188173983; called by muse, mutect2, varscan2
- DISP1 | c.3345C>T p.I1115= | Silent (SNP) | VAF 399/880 reads (45%) | catalogued as COSV52654274; called by muse, mutect2, varscan2
- DNAI4 | c.1701G>A p.R567= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV64020608; called by muse, mutect2, varscan2
- DOCK9 | c.2106C>T p.H702= (on ENST00000376460 / NM_001366676.2; = p.H703= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs765729652, COSV59618956; called by muse, mutect2, varscan2
- DST | c.7440C>T p.F2480= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV99759266; called by muse, mutect2, varscan2
- ECM1 | c.897C>T p.F299= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV60871555; called by muse, mutect2, varscan2
- FAM135B | c.2424C>T p.S808= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV52703033; called by muse, mutect2, varscan2
- FAT3 | c.5820C>T p.T1940= | Silent (SNP) | VAF 153/446 reads (34%) | catalogued as COSV53072730; called by muse, mutect2, varscan2
- FBXL7 | c.237C>T p.S79= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV61640716; called by muse, mutect2, varscan2
- FMO1 | c.1593C>T p.F531= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs1244936751, COSV61444522; called by muse, mutect2, varscan2
- FNDC7 | c.1590G>A p.R530= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV54750452; called by muse, mutect2, varscan2
- FOXF1 | c.183C>T p.I61= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV52284835; called by muse, mutect2, varscan2
- GGT1 | c.942C>T p.H314= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs1483858155, COSV50637847; called by mutect2, varscan2
- GOLGA3 | c.3504C>T p.R1168= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV52624796; called by muse, mutect2, varscan2
- GRIA4 | c.186T>C p.F62= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV56880398; called by muse, mutect2, varscan2
- GTF3C4 | c.435C>T p.F145= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV64644899; called by muse, mutect2, varscan2
- HECA | c.1068C>T p.I356= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV62768410; called by muse, mutect2, varscan2
- HNF1B | c.976C>T p.L326= | Silent (SNP) | VAF 197/557 reads (35%) | called by muse, mutect2, varscan2
- IKZF2 | c.1440C>T p.F480= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as rs754628466, COSV59576131; called by muse, mutect2, varscan2
- IL21 | c.51C>T p.V17= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV52645350; called by mutect2, varscan2
- ISLR | c.39G>A p.L13= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV51432874; called by muse, mutect2, varscan2
- ITPR1 | c.7215G>A p.G2405= (on ENST00000354582; = p.G2350= on NM_002222.7) | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV100232865; called by muse, mutect2, varscan2
- KCNJ1 | c.628C>T p.L210= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV60661242; called by muse, mutect2, varscan2
- KIF5C | c.882G>A p.G294= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs777704019, COSV68479692; called by muse, mutect2, varscan2
- LAMA2 | c.9327G>A p.L3109= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV101370887, COSV70337483; called by muse, mutect2, varscan2
- LILRA5 | c.585C>T p.F195= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV56641404, COSV56644254; called by muse, mutect2, varscan2
- LRP5 | c.1191C>T p.I397= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs1246734917, COSV53710879; called by muse, mutect2, varscan2
- LRRC18 | c.39C>T p.I13= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV53281875; called by muse, mutect2, varscan2
- MAGEB6B | c.303C>T p.S101= | Silent (SNP) | VAF 46/145 reads (32%) | catalogued as rs756386930; called by muse, mutect2, varscan2
- MALT1 | c.1200C>T p.L400= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV61933973; called by muse, varscan2
- MET | c.2703G>A p.L901= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as rs1374413099, COSV59256405; called by muse, mutect2, varscan2
- METTL2B | c.273G>A p.K91= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV52307562; called by muse, mutect2
- MINK1 | c.690C>T p.A230= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV61788526; called by muse, mutect2, varscan2
- MORC1 | c.1812G>A p.L604= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV51713306; called by muse, mutect2, varscan2
- MTOR | c.1302C>T p.F434= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV63868126; called by muse, mutect2, varscan2
- MUC16 | c.33699G>A p.E11233= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV67442474; called by muse, mutect2, varscan2
- MUC16 | c.19032C>T p.S6344= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs374525892; called by muse, mutect2, varscan2
- MUC16 | c.144C>T p.I48= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs753395613, COSV101200432, COSV67442499; called by muse, mutect2, varscan2
- NAV2 | c.1566G>A p.E522= (on ENST00000396087 / NM_001244963.2; = p.E499= on NM_145117.5) | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs1020841351, COSV62314704; called by muse, mutect2, varscan2
- NELL2 | c.2244G>A p.E748= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV61568292; called by muse, mutect2, varscan2
- NLRP14 | c.741C>T p.I247= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV55063663; called by muse, mutect2, varscan2
- NMUR1 | c.1002C>T p.F334= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as rs149953749; called by muse, mutect2, varscan2
- NPBWR2 | c.502C>T p.L168= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV63899746; called by muse, mutect2, varscan2
- NPR2 | c.1161C>T p.D387= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as COSV61308845; called by muse, mutect2, varscan2
- NPY5R | c.813C>T p.L271= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs769907339, COSV58450868; called by muse, mutect2, varscan2
- OBSCN | c.12183C>T p.L4061= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs1433874309, COSV52737076; called by muse, mutect2, varscan2
- OR10G4 | c.930G>A p.R310= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV57976487; called by muse, mutect2, varscan2
- OR10G8 | c.768C>T p.F256= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV70908377; called by muse, varscan2
- OR13G1 | c.126C>T p.I42= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV62943298; called by muse, mutect2, varscan2
- OR2G3 | c.906G>A p.R302= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV60680702; called by muse, mutect2, varscan2
- OR2G6 | c.135C>T p.L45= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as COSV58573593; called by muse, mutect2, varscan2
- OR2M4 | c.534C>T p.F178= | Silent (SNP) | VAF 55/157 reads (35%) | catalogued as COSV60707115; called by muse, mutect2, varscan2
- OR4S2 | c.478C>T p.L160= | Silent (SNP) | VAF 64/101 reads (63%) | catalogued as COSV56745513, COSV99044723; called by muse, mutect2, varscan2
- OR51F2 | c.141C>T p.I47= | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as COSV59063625; called by muse, mutect2
- OR52D1 | c.672C>T p.I224= | Silent (SNP) | VAF 29/176 reads (16%) | catalogued as COSV59486911; called by muse, mutect2, varscan2
- OR52M1 | c.832C>T p.L278= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV64171354; called by muse, mutect2, varscan2
- OR5B3 | c.138G>A p.L46= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV58676250; called by muse, mutect2, varscan2
- OR5M1 | c.255C>T p.F85= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV73201948; called by muse, mutect2, varscan2
- P2RX7 | c.555C>G p.A185= | Silent (SNP) | VAF 44/304 reads (14%) | catalogued as COSV55853130; called by muse, mutect2, varscan2
- P2RY2 | c.975C>T p.G325= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV60775273; called by muse, mutect2
- PAPPA2 | c.4740G>A p.L1580= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as rs200572315, COSV100868236, COSV62790135; called by mutect2, varscan2
- PARD3 | c.3837C>T p.V1279= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs1412867572, COSV61047271; called by mutect2, varscan2
- PCDHB11 | c.1845C>T p.F615= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV100697148; called by muse, mutect2, varscan2
- PCDHGA9 | c.2247C>T p.F749= | Silent (SNP) | VAF 36/64 reads (56%) | catalogued as COSV53894319; called by muse, mutect2, varscan2
- PDE4DIP | c.7009C>T p.L2337= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs781862801, COSV100517914; called by muse, mutect2, varscan2
- PGLYRP4 | c.927C>T p.F309= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV62834487; called by muse, mutect2, varscan2
- PKHD1L1 | c.2403G>A p.T801= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs267601713, COSV65736382; called by muse, mutect2, varscan2
- PLA2G4F | c.1746C>T p.F582= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as COSV51825306; called by muse, mutect2, varscan2
- PLEC | c.9351G>A p.L3117= (on ENST00000322810 / NM_201380.4; = p.L3007= on NM_000445.5) | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs1554683320, COSV59601200; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1308G>A p.K436= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV62610635, COSV62611464; called by muse, mutect2, varscan2
- PNPLA8 | c.975A>G p.E325= | Silent (SNP) | VAF 36/183 reads (20%) | catalogued as COSV57551207; called by muse, mutect2, varscan2
- POLE | c.3864C>T p.A1288= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV57673520; called by mutect2, varscan2
- POTEE | c.456C>T p.V152= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as COSV58223475; called by muse, mutect2, varscan2
- PRKCB | c.1998G>A p.E666= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV57764583; called by muse, mutect2, varscan2
- PRLR | c.1209C>T p.I403= | Silent (SNP) | VAF 65/219 reads (30%) | catalogued as COSV51492899; called by muse, mutect2, varscan2
- PRX | c.2118C>T p.L706= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as COSV52527421; called by muse, mutect2, varscan2
- PTCD1 | c.327C>T p.F109= | Silent (SNP) | VAF 110/234 reads (47%) | catalogued as COSV52856167; called by muse, varscan2
- PTPRA | c.669G>A p.V223= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV53777950; called by muse, mutect2, varscan2
- PTPRB | c.216C>T p.S72= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV51724067; called by muse, mutect2, varscan2
- RAB4B | c.351C>T p.I117= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV63824243; called by muse, mutect2
- RFX2 | c.303C>T p.A101= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as COSV57938897; called by muse, mutect2, varscan2
- RPRD2 | c.1149C>T p.I383= | Silent (SNP) | VAF 61/273 reads (22%) | catalogued as rs911649247, COSV64818517; called by muse, mutect2, varscan2
- SCAMP5 | c.429G>A p.T143= | Silent (SNP) | VAF 65/215 reads (30%) | catalogued as rs778160445, COSV62642807; called by muse, mutect2, varscan2
- SCN11A | c.2292C>T p.I764= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV56565107; called by muse, mutect2, varscan2
- SIDT1 | c.738C>T p.I246= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV53497917; called by muse, mutect2, varscan2
- SIGIRR | c.303G>A p.Q101= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV58985786; called by muse, mutect2, varscan2
- SLC22A8 | c.1437G>A p.G479= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs761442704, COSV60323379; called by muse, mutect2, varscan2
- SLC34A2 | c.1764G>A p.Q588= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as COSV65940511; called by muse, mutect2, varscan2
- SLC35F5 | c.1069T>C p.L357= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV55516780; called by muse, mutect2, varscan2
- SLCO1B3 | c.1596G>A p.R532= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs914821884, COSV53931615; called by muse, mutect2, varscan2
- SLCO5A1 | c.1056C>T p.L352= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs756987021, COSV52653134; called by muse, mutect2, varscan2
- SNRPC | c.408C>T p.P136= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV55074660; called by muse, mutect2, varscan2
- SORL1 | c.2415C>T p.S805= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs532535284, COSV52748908; called by muse, mutect2, varscan2
- SPG11 | c.3807A>G p.R1269= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs1240361024, COSV55990450; called by muse, mutect2, varscan2
- SPRYD3 | c.73C>T p.L25= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV56852200; called by muse, mutect2, varscan2
- SSH1 | c.1461C>T p.T487= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs766848853, COSV100425806; called by muse, mutect2, varscan2
- ST8SIA3 | c.69G>A p.L23= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV60653227; called by muse, mutect2, varscan2
- SYNGR4 | c.462C>T p.I154= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV61225029; called by muse, mutect2, varscan2
- SYT11 | c.654C>T p.T218= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV64173628; called by muse, mutect2, varscan2
- TECTA | c.3510C>T p.I1170= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs747924317, COSV50687689; called by muse, mutect2, varscan2
- TLCD4 | c.780A>G p.G260= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs761527873, COSV64631292; called by muse, mutect2, varscan2
- TMC2 | c.1422C>T p.I474= | Silent (SNP) | VAF 43/186 reads (23%) | catalogued as COSV62649488; called by muse, mutect2, varscan2
- TMED1 | c.486G>A p.R162= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs187693148, COSV53033080; called by mutect2, varscan2
- TMEM132B | c.1524C>T p.F508= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as rs770207028, COSV54743667, COSV54771431; called by muse, mutect2, varscan2
- TNS1 | c.5175C>T p.S1725= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as COSV99411688; called by muse, mutect2, varscan2
- TRIM43 | c.180G>A p.P60= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs754163909, COSV99719907; called by mutect2, varscan2
- TRMT5 | c.306G>A p.R102= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as rs1261461753, COSV50780913; called by muse, mutect2, varscan2
- TRPC5 | c.1665G>A p.G555= | Silent (SNP) | VAF 58/212 reads (27%) | catalogued as COSV53283263; called by muse, mutect2, varscan2
- TRPM3 | c.1656C>T p.F552= (on ENST00000357533 / NM_001366142.2; = p.F397= on NM_024971.6) | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs201162468; called by muse, mutect2, varscan2
- TSSK4 | c.927G>A p.E309= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV55302308; called by muse, mutect2, varscan2
- TTN | c.22722C>T p.I7574= (on ENST00000591111; = p.I6647= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV59870823; called by muse, mutect2, varscan2
- TUBB2A | c.270C>T p.F90= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs562003687, COSV61318705; called by muse, mutect2, varscan2
- TUBGCP2 | c.1822C>T p.L608= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV53302593; called by muse, mutect2, varscan2
- VPS18 | c.1362G>A p.E454= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV55028690; called by muse, mutect2, varscan2
- VPS39 | c.1597C>T p.L533= (on ENST00000348544 / NM_001301138.2; = p.L522= on NM_015289.5) | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV58787529; called by muse, mutect2, varscan2
- VSIG1 | c.672C>T p.I224= | Silent (SNP) | VAF 54/312 reads (17%) | catalogued as rs745578688, COSV54257528; called by muse, mutect2, varscan2
- WDR90 | c.1980C>T p.P660= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs530269746, COSV53466142, COSV53473513; called by muse, mutect2
- WIZ | c.4137A>C p.P1379= (on ENST00000673675 / NM_001371589.1; = p.P284= on NM_021241.3) | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1255838885, COSV54604330; called by muse, varscan2
- ZC3H18 | c.72G>A p.S24= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs751929593, COSV99964386; called by mutect2, varscan2
- ZNF280C | c.1755T>C p.A585= | Silent (SNP) | VAF 42/263 reads (16%) | catalogued as COSV63968438; called by muse, mutect2, varscan2
- ABCD3 | c.684+216G>A | Intron (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100239055; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852377 G>A | 3'Flank (SNP) | VAF 6/19 reads (32%) | catalogued as rs758242680; called by mutect2, varscan2
- ANKRD13D | c.*659A>T | 3'UTR (SNP) | VAF 18/66 reads (27%) | catalogued as COSV57750561; called by muse, mutect2, varscan2
- C16orf82 | c.-2C>T | 5'UTR (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- CCDC140 | n.768C>T | RNA (SNP) | VAF 13/45 reads (29%) | catalogued as COSV54674694; called by muse, varscan2
- MIR525 | n.63C>T | RNA (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- SLC5A1 | chr22:32039567 G>A | 5'Flank (SNP) | VAF 46/151 reads (30%) | catalogued as rs374471950; called by muse, mutect2, varscan2
- SNRPN | chr15:24982068 C>T | 3'Flank (SNP) | VAF 78/233 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.10360+2497G>A | Intron (SNP) | VAF 15/48 reads (31%) | catalogued as rs757533998, COSV59908532; called by muse, mutect2, varscan2
- XKR6 | c.765-110404C>T | Intron (SNP) | VAF 21/48 reads (44%) | catalogued as rs367974235; called by muse, mutect2, varscan2
